HCMI case HCM-CSHL-0607-C19 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d8b5fbeb-3c4c-424c-a1e7-5a7a085b005a

Demographics
Sex at birth: male; Year of birth: 1943; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C19.9; Tissue or organ of origin: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 75.4 years (27,554 days); AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Sites of involvement: Liver.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 42 days; Days to treatment end: 780 days (2.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Treatment intent type: Neoadjuvant; Days to treatment start: 42 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRI; Days to treatment start: 42 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 42 days; Days to treatment end: 780 days (2.1 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 236 days.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 76.1 years (27,812 days); Days to diagnosis: 258 days.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cetuximab; Treatment intent type: Maintenance Therapy; Days to treatment start: 42 days; Days to treatment end: 192 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFIRI; Days to treatment start: 42 days; Days to treatment end: 192 days; Treatment outcome: Treatment Ongoing.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 839 days (2.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 411.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 178 cm; BMI: 25.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Days to comorbidity: 236 days; Days to risk factor: 236 days; Risk factors: Colon Polyps.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples)
- Samples HCM-CSHL-0607-C19-10A, HCM-CSHL-0607-C19-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0607-C19-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
